Somatic mutation profile of tumor specimen TARGET-30-PASLDM-01A (aliquot TARGET-30-PASLDM-01A-01D) from TARGET case TARGET-30-PASLDM, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 5.2 years (1,897 days).
Specimen TARGET-30-PASLDM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3e2f161-b955-4ab3-9e52-f3115cfc2b90.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASLDM-10A (Blood Derived Normal), aliquot TARGET-30-PASLDM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db92a6b6-9d5d-4f75-90ed-9da7f961321a

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.1716A>T p.K572N | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV64216796; called by muse, mutect2, varscan2
- HERC1 | c.12249G>T p.Q4083H | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs748225638, COSV71251409; called by muse, mutect2, varscan2
- KCNH4 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV52922099; called by muse, mutect2, varscan2
- TRPS1 | c.1260C>A p.L420= (on ENST00000220888 / NM_001330599.2; = p.L433= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as COSV55268832; called by muse, mutect2, varscan2
- AR | c.*4093C>A | 3'UTR (SNP) | VAF 71/208 reads (34%) | catalogued as COSV65965512; called by muse, mutect2, varscan2
- CREBBP | c.*1130_*1131insA | 3'UTR (INS) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
